Somatic mutation profile of tumor specimen TCGA-3M-AB46-01A (aliquot TCGA-3M-AB46-01A-11D-A410-08) from TCGA case TCGA-3M-AB46, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lesser curvature of stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2.
Specimen TCGA-3M-AB46-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48c389c4-01ee-4732-9b22-da36ac247690.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3M-AB46-10A (Blood Derived Normal), aliquot TCGA-3M-AB46-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/043fd083-a28b-4576-82ca-f5dc9ee47738

The open-access MAF lists 203 somatic variants for this specimen: 158 protein-altering or splice-affecting, 39 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 39, Frame Shift Del 14, Nonsense Mutation 7, In Frame Del 7, Splice Site 7, Intron 3, 3'UTR 2, Frame Shift Ins 1, In Frame Ins 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.371G>C p.C124S | Missense Mutation (SNP) | VAF 44/82 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM041823, CM110163, COSV64289150, COSV64290215, COSV64293195; called by muse, mutect2, varscan2
- A1BG | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV99568194; called by muse, mutect2, varscan2
- A1CF | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV50981317, COSV99255315; called by muse, mutect2, varscan2
- ABCC2 | c.1074G>C p.W358C | Missense Mutation (SNP) | VAF 114/306 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64971227; called by muse, mutect2, varscan2
- ADAMTS5 | c.1656A>T p.K552N | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.415); catalogued as COSV99537075; called by muse, mutect2, varscan2
- ADGRB3 | c.1441A>T p.T481S | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1202543365, COSV100999896; called by muse, mutect2, varscan2
- AGAP4 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 89/222 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101432609; called by muse, mutect2, varscan2
- ANK2 | c.4408G>A p.D1470N | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.167); catalogued as rs564648496, COSV52147187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD42 | c.366G>A p.V122= | Splice Region (SNP) | VAF 6/138 reads (4%) | catalogued as COSV99473534; called by muse, mutect2
- ANKRD42 | c.366+1G>T p.X122_splice | Splice Site (SNP) | VAF 6/137 reads (4%) | catalogued as COSV99473536; called by muse, mutect2
- AP4B1 | c.2171T>A p.I724N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV99870578; called by muse, mutect2, varscan2
- APOD | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV100581035; called by muse, mutect2, varscan2
- ARID2 | c.5216C>G p.A1739G | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100535458; called by muse, mutect2, varscan2
- ARMC8 | c.1177T>A p.L393M (on ENST00000469044 / NM_001363941.2; = p.L379M on NM_015396.6) | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as COSV100509407; called by muse, mutect2, varscan2
- ATP9A | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100124362; called by muse, mutect2, varscan2
- BMPER | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as COSV51818730, COSV99778921; called by muse, mutect2, varscan2
- CADM4 | c.940G>C p.V314L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.087); catalogued as COSV99731375; called by muse, mutect2, varscan2
- CCDC146 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs752173458, COSV99592189; called by muse, mutect2, varscan2
- CHRDL1 | c.1087G>T p.E363* (on ENST00000372045; = p.E369* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV54326838, COSV99487731; called by muse, mutect2
- CIITA | c.3311C>T p.T1104M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs367805896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMYA5 | c.7380G>C p.L2460F | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV101483861, COSV71405217; called by muse, mutect2, varscan2
- COL16A1 | c.3068C>G p.P1023R | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99593632; called by muse, mutect2, varscan2
- COMMD10 | c.86G>T p.R29I | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV57238714, COSV99174511; called by muse, mutect2, varscan2
- CROCC | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.301); catalogued as COSV100978065; called by muse, mutect2, varscan2
- CSMD3 | c.3680G>A p.R1227Q (on ENST00000297405 / NM_001363185.1; = p.R1123Q on NM_052900.3) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1411756886, COSV99825676; called by muse, mutect2, varscan2
- CSNK1E | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868029992, COSV63290315; called by muse, mutect2
- CTDSPL | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.548); catalogued as COSV99828529; called by muse, mutect2, varscan2
- CTR9 | c.1832G>C p.W611S | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV100797263; called by muse, mutect2, varscan2
- CYP2R1 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV100584856; called by muse, mutect2, varscan2
- DCHS1 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100201528; called by muse, mutect2, varscan2
- DDN | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); catalogued as COSV100304902, COSV60292318; called by muse, mutect2, varscan2
- DDX23 | c.960T>G p.Y320* | Nonsense Mutation (SNP) | VAF 154/427 reads (36%) | catalogued as COSV100339620; called by muse, mutect2, varscan2
- DIDO1 | c.187C>A p.R63S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99824873, COSV99827346; called by muse, mutect2
- DMRT1 | c.1094T>C p.V365A | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs1167986419, COSV101206616; called by muse, mutect2, varscan2
- DNAH2 | c.11386C>T p.R3796C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762729742, COSV101209032; called by muse, mutect2, varscan2
- ELMO1 | c.1300+1G>A p.X434_splice | Splice Site (SNP) | VAF 32/81 reads (40%) | catalogued as rs1486694290, COSV60295508; called by muse, mutect2, varscan2
- ENKD1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 84/138 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs538477292, COSV99537439; called by muse, mutect2, varscan2
- F5 | c.2747G>C p.G916A | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100888925; called by muse, mutect2, varscan2
- FAAH | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs200172860, COSV99679889; called by muse, varscan2
- FAM221B | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs941850395, COSV100941291, COSV100941340; called by muse, mutect2, varscan2
- FAM43B | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV100261461, COSV60579992; called by muse, mutect2, varscan2
- FBXW7 | c.1500T>A p.H500Q (on ENST00000281708 / NM_001349798.2; = p.H420Q on NM_018315.5) | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99654618, COSV99654778; called by muse, mutect2, varscan2
- FLG | c.6154G>C p.E2052Q | Missense Mutation (SNP) | VAF 204/724 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); catalogued as COSV100910572, COSV64245868; called by muse, mutect2, varscan2
- FMO1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs1378382863, COSV61445367; called by muse, mutect2, varscan2
- FMO2 | c.998T>C p.F333S | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV99268915; called by muse, mutect2, varscan2
- G2E3 | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99249339; called by muse, mutect2, varscan2
- GOLGB1 | c.6514G>A p.E2172K | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100510363; called by muse, mutect2, varscan2
- GRIN2A | c.3721C>T p.R1241W | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1303700994, COSV58027213; called by muse, mutect2, varscan2
- HECTD4 | c.9047C>G p.S3016C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101106755; called by muse, mutect2, varscan2
- HNRNPM | c.2045C>A p.A682D | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV55313226, COSV99725232; called by muse, mutect2, varscan2
- IPO7 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760720332, COSV63352914; called by muse, mutect2, varscan2
- IRF2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1162875123, COSV66929213; called by muse, mutect2, varscan2
- ISLR | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs146746279; called by muse, mutect2, varscan2
- IYD | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV99989310; called by muse, mutect2, varscan2
- JAG1 | c.2704T>C p.C902R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99652461; called by muse, mutect2, varscan2
- KCNC2 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV100128262; called by muse, mutect2, varscan2
- KRAS | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV99767887; called by muse, mutect2, varscan2
- KRT84 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV99230728, COSV99230821; called by muse, mutect2, varscan2
- KRTAP1-5 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100721358; called by muse, mutect2, varscan2
- KRTAP26-1 | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100860373; called by muse, mutect2, varscan2
- LAMA5 | c.4938+2T>C p.X1646_splice | Splice Site (SNP) | VAF 31/115 reads (27%) | catalogued as COSV99438215; called by muse, mutect2, varscan2
- LRP1B | c.7011G>T p.W2337C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101253036; called by muse, mutect2, varscan2
- LRP1B | c.3935T>C p.I1312T | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101253037, COSV67192454; called by muse, mutect2, varscan2
- LUC7L3 | c.1237A>G p.K413E | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV99536740; called by muse, mutect2, varscan2
- MAP1A | c.8178C>A p.D2726E | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100288129; called by muse, mutect2, varscan2
- MARCHF3 | c.622T>G p.C208G | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV100427696; called by muse, mutect2, varscan2
- MARCHF7 | c.1765C>G p.Q589E | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV99373526; called by muse, varscan2
- MATN3 | c.588T>A p.D196E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101337432; called by muse, mutect2, varscan2
- MCM2 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99413587; called by muse, mutect2
- MRM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as rs780423593; called by muse, mutect2, varscan2
- MSL2 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99386489; called by muse, mutect2, varscan2
- MTF1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 39/104 reads (38%) | catalogued as COSV100888576; called by muse, mutect2, varscan2
- MTHFD1L | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs771532672, COSV100943186; called by muse, mutect2, varscan2
- MYH13 | c.497T>G p.M166R | Missense Mutation (SNP) | VAF 73/118 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99352431; called by muse, mutect2, varscan2
- MYORG | c.1159G>C p.V387L | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1465014941, COSV52628733, COSV99898362; called by muse, mutect2
- NAA25 | c.2890C>G p.L964V | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99927294; called by muse, mutect2
- NAB2 | c.124del p.E42Sfs*62 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | catalogued as COSV100272773; called by pindel, varscan2
- NANP | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100504982; called by muse, mutect2
- NF1 | c.2585C>T p.T862I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.196); catalogued as CM143347, COSV100646080; called by muse, mutect2, varscan2
- NLRP3 | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100275308; called by muse, mutect2
- NOS1AP | c.534G>C p.Q178H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100722842, COSV62639774; called by muse, mutect2, varscan2
- NRIP3 | c.638A>G p.H213R | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100487067; called by muse, mutect2, varscan2
- NUTM1 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.253); catalogued as COSV100412105; called by muse, mutect2, varscan2
- ODF2 | c.393G>C p.M131I (on ENST00000434106 / NM_153433.2; = p.M107I on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV100654438, COSV100654920; called by muse, mutect2, varscan2
- OR1L1 | c.961C>A p.Q321K (on ENST00000373686; = p.Q271K on NM_001005236.3) | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.098); catalogued as COSV100542092, COSV58936571; called by muse, mutect2, varscan2
- OR2T2 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV61618706; called by muse, mutect2, varscan2
- OR4N5 | c.28A>C p.T10P | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV100374034; called by muse, mutect2
- PAPPA2 | c.3840T>G p.I1280M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV100867605; called by muse, mutect2, varscan2
- PBXIP1 | c.898A>T p.M300L | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100870012; called by muse, mutect2, varscan2
- PER1 | c.1649G>C p.C550S | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100424284; called by muse, mutect2, varscan2
- PLEKHA5 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100163595; called by muse, mutect2, varscan2
- POLR2C | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV99538220; called by muse, mutect2, varscan2
- PRR19 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs972798619, COSV100003601; called by muse, mutect2, varscan2
- PRR30 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99574321; called by muse, mutect2
- PRUNE2 | c.3969A>T p.Q1323H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV100944243; called by muse, mutect2, varscan2
- PSD4 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV99830850; called by muse, mutect2, varscan2
- PTPRN | c.2573A>C p.N858T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99833703; called by muse, mutect2, varscan2
- PUF60 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs866435737, COSV100512906; called by muse, mutect2, varscan2
- RABEP1 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99336321; called by muse, mutect2, varscan2
- RASGEF1A | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as rs772367967, COSV100988641, COSV100988733; called by muse, mutect2
- RNF112 | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101465390; called by muse, mutect2, varscan2
- RSAD1 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99364129; called by muse, mutect2, varscan2
- RYR2 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs748867973, COSV100768198; called by muse, mutect2, varscan2
- SDE2 | c.407G>C p.R136P | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55253292, COSV99682463; called by muse, mutect2, varscan2
- SHOC1 | c.3286A>T p.I1096F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100597298; called by muse, mutect2, varscan2
- SIPA1 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1277108648; called by muse, varscan2
- SLIT3 | c.2364C>A p.S788R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV100265564; called by muse, mutect2, varscan2
- SMURF1 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV100742362; called by muse, mutect2, varscan2
- SRCAP | c.7811C>G p.P2604R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV99349370; called by muse, mutect2, varscan2
- SRL | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV68423415; called by muse, mutect2, varscan2
- STAM | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101092180; called by muse, mutect2, varscan2
- STK40 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs773276972, COSV63737343; called by muse, mutect2
- STXBP5L | c.2068C>T p.R690* | Nonsense Mutation (SNP) | VAF 34/86 reads (40%) | catalogued as rs758895320, COSV99872168; called by muse, mutect2, varscan2
- TBCC | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99773935; called by muse, mutect2, varscan2
- TENM2 | c.836G>A p.R279Q (on ENST00000518659 / NM_001122679.2; = p.R88Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.968); catalogued as rs777331927, COSV69133127; called by muse, mutect2
- TENM4 | c.1987A>C p.M663L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99571397; called by muse, mutect2
- TMEM94 | c.1136T>G p.L379R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100050140; called by muse, mutect2, varscan2
- TRIM56 | c.1606C>A p.L536I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as COSV100047003; called by muse, mutect2, varscan2
- TSHZ3 | c.2902A>C p.N968H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV99550704; called by muse, mutect2, varscan2
- TTC3 | c.5650G>C p.D1884H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100695082, COSV61293935; called by muse, mutect2, varscan2
- TTN | c.21851A>T p.Q7284L (on ENST00000591111; = p.Q6357L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/204 reads (34%) | PolyPhen benign (0.035); catalogued as COSV100595817; called by muse, mutect2, varscan2
- TUBA1B | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 58/150 reads (39%) | catalogued as COSV100254052; called by muse, mutect2, varscan2
- UCMA | c.401A>C p.N134T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV101095404; called by muse, varscan2
- WNT10B | c.558del p.S187Afs*53 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as COSV99975723; called by mutect2, pindel, varscan2
- WSB1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 142/258 reads (55%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as rs774909949, COSV99285906; called by muse, mutect2, varscan2
- ZBED8 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as COSV101283466, COSV68824947; called by muse, mutect2, varscan2
- ZNF17 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100299918; called by muse, mutect2
- ZNF318 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 91/474 reads (19%) | catalogued as COSV100545962; called by muse, mutect2, varscan2
- ZNF589 | c.284A>G p.Q95R | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV100685548; called by muse, mutect2, varscan2
- ZNF667 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs772709398, COSV52631430; called by muse, mutect2, varscan2
- ZP4 | c.522A>C p.E174D | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.18); catalogued as COSV100850583; called by muse, mutect2, varscan2
- AOAH | c.638_650del p.V213Efs*66 | Frame Shift Del (DEL) | VAF 39/191 reads (20%) | called by mutect2, pindel, varscan2
- DNAJC28 | c.795_815del p.D265_R271del | In Frame Del (DEL) | VAF 46/181 reads (25%) | called by mutect2, pindel, varscan2
- ETV6 | c.1153-23_1171del p.X385_splice | Splice Site (DEL) | VAF 28/58 reads (48%) | called by mutect2, pindel
- EXOC3L2 | c.2034_2035del p.H679Ffs*3 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- FAM120AOS | c.67_77del p.S23Kfs*166 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- FLG | c.7321dup p.S2441Ffs*44 | Frame Shift Ins (INS) | VAF 110/535 reads (21%) | called by mutect2, pindel, varscan2
- FOXD4L6 | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by mutect2, varscan2
- FREM1 | c.5786_5796+7del p.X1929_splice | Splice Site (DEL) | VAF 10/17 reads (59%) | called by mutect2, varscan2
- INPP4B | c.2709_2714dup p.Q904_L905dup | In Frame Ins (INS) | VAF 32/60 reads (53%) | called by mutect2, varscan2
- KIAA0232 | c.1106del p.P369Lfs*2 | Frame Shift Del (DEL) | VAF 32/71 reads (45%) | called by mutect2, pindel, varscan2
- MARCHF7 | c.1643_1681delinsGTGACTTATGTAGAATTTGTCAAATGGCAGCTG p.E548_S561delinsGDLCRICQMAAA | In Frame Del (DEL) | VAF 21/136 reads (15%) | called by pindel, varscan2*
- MMP28 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOF | c.3894_3913del p.R1298Sfs*3 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- PHGDH | c.447_464del p.L151_I156del | In Frame Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- RB1 | c.2049_2063del p.F684_L688del | In Frame Del (DEL) | VAF 68/104 reads (65%) | called by mutect2, pindel, varscan2
- RETREG3 | c.553_568del p.R185Ffs*6 | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | called by mutect2, pindel, varscan2
- RNF11 | c.225_248del p.L76_G83del | In Frame Del (DEL) | VAF 27/100 reads (27%) | called by mutect2, pindel
- SERPINB3 | c.980del p.G327Efs*23 | Frame Shift Del (DEL) | VAF 29/65 reads (45%) | called by mutect2, pindel, varscan2
- SIPA1 | c.389_395del p.P130Lfs*44 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | called by pindel, varscan2
- SYMPK | c.533_539del p.G178Afs*74 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- TAF6L | c.548_559del p.L183_N186del | In Frame Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- TMCO3 | c.1357_1366del p.V453Sfs*4 | Frame Shift Del (DEL) | VAF 30/252 reads (12%) | called by mutect2, pindel, varscan2
- TP53 | c.842_845del p.D281Gfs*63 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- USP54 | c.2280del p.K760Nfs*6 | Frame Shift Del (DEL) | VAF 85/170 reads (50%) | called by mutect2, pindel, varscan2
- UTRN | c.8496-15_8496-2del p.X2832_splice | Splice Site (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- ZNF333 | c.303_306+10del p.X101_splice | Splice Site (DEL) | VAF 38/155 reads (25%) | called by pindel, varscan2
- ZNF490 | c.387_389del p.E129del | In Frame Del (DEL) | VAF 38/124 reads (31%) | called by pindel, varscan2
- ACOX2 | c.1140C>T p.F380= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100250016; called by muse, mutect2, varscan2
- ADAMTS2 | c.942C>G p.V314= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99201072; called by muse, mutect2, varscan2
- ARHGAP15 | c.1065G>C p.L355= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99708586; called by muse, mutect2, varscan2
- ATP13A2 | c.2319G>T p.L773= | Silent (SNP) | VAF 58/106 reads (55%) | catalogued as COSV100453931; called by muse, mutect2, varscan2
- CCN5 | c.648G>T p.V216= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV99509175; called by muse, varscan2
- CMYA5 | c.11949C>T p.C3983= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV101405642; called by muse, mutect2, varscan2
- DPAGT1 | c.1143G>A p.L381= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV99597818; called by muse, mutect2, varscan2
- DQX1 | c.1026A>C p.S342= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as COSV101098757; called by muse, mutect2, varscan2
- DUSP8 | c.486C>A p.T162= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV100524226; called by muse, mutect2, varscan2
- EHHADH | c.297C>T p.F99= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs555441588, COSV51630795; called by muse, mutect2, varscan2
- ERGIC1 | c.123C>G p.L41= | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- GAS2L2 | c.2457G>A p.V819= | Silent (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- GSE1 | c.3135C>T p.S1045= | Silent (SNP) | VAF 56/100 reads (56%) | catalogued as rs1250279072, COSV99496081; called by muse, mutect2, varscan2
- HKDC1 | c.2356C>T p.L786= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100664388; called by muse, mutect2, varscan2
- INPP5K | c.1296G>A p.P432= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as rs142054151; called by muse, mutect2, varscan2
- KIF5C | c.2358G>A p.G786= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as COSV101276093; called by muse, mutect2, varscan2
- LRP1B | c.13344G>C p.V4448= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV101253034, COSV67222025; called by muse, varscan2
- LRRTM1 | c.1101C>T p.A367= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1437847971, COSV99701878; called by muse, mutect2
- MAP3K3 | c.1482C>T p.N494= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV99368448; called by muse, mutect2, varscan2
- MEFV | c.819G>C p.S273= | Silent (SNP) | VAF 74/232 reads (32%) | catalogued as rs962267537, COSV54819966, COSV99560305; called by muse, mutect2, varscan2
- NAB2 | c.126G>A p.E42= | Silent (SNP) | VAF 26/94 reads (28%) | called by muse, varscan2
- NLRP3 | c.36G>T p.L12= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV100275305; called by muse, mutect2
- PDS5B | c.2199C>T p.I733= | Silent (SNP) | VAF 9/167 reads (5%) | catalogued as COSV100220522; called by muse, mutect2
- PGBD2 | c.33G>A p.G11= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs151216713; called by muse, mutect2, varscan2
- PIP5KL1 | c.747C>G p.G249= (on ENST00000388747 / NM_001135219.2; = p.G46= on NM_173492.1) | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100304787; called by muse, mutect2, varscan2
- PKD1 | c.2736G>A p.V912= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99237221; called by muse, mutect2, varscan2
- PLCD3 | c.699C>T p.S233= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1340217620, COSV100504092; called by muse, mutect2, varscan2
- PLEKHH2 | c.2181T>G p.L727= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV99174361; called by muse, mutect2, varscan2
- SGO2 | c.426G>A p.K142= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100764601; called by muse, mutect2, varscan2
- SLC25A37 | c.714C>T p.I238= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs766994831, COSV99263845; called by muse, mutect2, varscan2
- SMG9 | c.417G>A p.G139= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs560467760, COSV99526620; called by muse, varscan2
- TAS2R16 | c.87T>C p.V29= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99972183; called by muse, mutect2, varscan2
- TNR | c.534C>T p.H178= | Silent (SNP) | VAF 96/172 reads (56%) | catalogued as rs550741218, COSV99686987, COSV99687755; called by muse, mutect2, varscan2
- VSTM2A | c.174T>C p.Y58= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100172917; called by muse, mutect2
- WDSUB1 | c.72C>A p.L24= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV100701755; called by muse, mutect2, varscan2
- XYLT2 | c.2268C>T p.L756= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99190690; called by muse, mutect2
- YEATS4 | c.612T>C p.S204= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV99923912; called by muse, mutect2, varscan2
- ZNF148 | c.1209G>A p.Q403= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV100641981, COSV62306803; called by muse, mutect2, varscan2
- ZNF275 | c.402C>T p.C134= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs1017861669, COSV100936157; called by muse, mutect2, varscan2
- AFDN | chr6:167825733 C>G | 5'Flank (SNP) | VAF 53/171 reads (31%) | called by muse, mutect2, varscan2
- CIRBP | c.-7+445G>C | Intron (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100309701; called by muse, mutect2, varscan2
- CLCN3 | c.2367-2099A>G | Intron (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100641595; called by muse, mutect2, varscan2
- FBXW7 | c.502-2392_502-2384del | Intron (DEL) | VAF 3/39 reads (8%) | called by mutect2, pindel
- FGFR3 | c.*1310C>T | 3'UTR (SNP) | VAF 5/14 reads (36%) | catalogued as COSV53402213; called by muse, mutect2, varscan2
- RNASEH1 | c.*2C>G | 3'UTR (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100177018; called by muse, mutect2, varscan2
